Gene-level copy-number profile of tumor specimen C3L-02546-03 from CPTAC case C3L-02546, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 74.6 years (27,236 days).
Specimen C3L-02546-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f437c151-f841-46c9-ac77-1990866324ac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02546-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/8832030f-3ac9-4150-9f53-a90015b4519d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 521; copy number 1: 5,383; copy number 2: 31,797; copy number 3: 15,412; copy number 4: 5,577; copy number 5: 22; copy number 6: 111; copy number 9: 17; copy number 10: 42; copy number 12: 30.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:173,699,082–174,001,488, 2 genes (within-gene range 0–2): LINC02269, AC106895.1.
- chr8:3,373,353–3,375,226, 1 gene (within-gene range 0–1): AC026991.1.
- chr8:3,700,492–3,700,628, 1 gene (within-gene range 0–1): RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 221 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:218,298–5,490,220, 106 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr11:32,112,049–37,726,456, 96 genes, copy number 5–12 (broad region; genes not listed).
- chr14:106,703,846–106,879,812, 19 genes, copy number 5: IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.

Autosomal genes at a single copy (total copy number 1): 4,518. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
